TARGET case TARGET-15-SJMLL003311 — Acute Lymphoblastic Leukemia - Phase III (TARGET-ALL-P3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b776552f-1442-420d-8ffe-fd71bc1e6fa1

Demographics
Sex at birth: female; Age at index: 11 years; Vital status: Dead; Days to death: 39 days.

Diagnoses (1)
1. Acute lymphocytic leukemia: ICD-O-3 morphology code: 9835/3; ICD-10 code: C91.0; Tissue or organ of origin: Bone marrow; Classification of tumor: primary; Age at diagnosis: 11.9 years (4,330 days); Year of diagnosis: 1998; Days to last follow up: 39 days.

Follow-up (1 entry)
- Days to follow up: 39 days; Event-free: no event (relapse, second malignancy or death) recorded through day 39; Year of follow up: 1998.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 0: Leukocytes 25.6 ×10³/µL.

Biospecimens (3 samples)
- Samples TARGET-15-SJMLL003311-09A.1, TARGET-15-SJMLL003311-09A.2 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
- Sample TARGET-15-SJMLL003311-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_ALL_ClinicalData_Phase_III_20230725.xlsx:
- Overall Survival Time in Days: 39
- Protocol: St. Jude
- WBC at Diagnosis: 25.6
- Karyotype: 46,XX,t(11;19)(q23;p13.1)[20]
- WHO ALAL Classification: MLL
- WHO Dx: MLL
